TARGET case TARGET-30-PARGHY — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Retroperitoneum and peritoneum. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3cb554d8-eda9-5d7d-8ffe-3c08b9f4707f

Demographics
Sex at birth: male; Race: asian; Ethnicity: not hispanic or latino; Age at index: 3 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 3.4 years (1,229 days); Year of diagnosis: 2007; Days to last follow up: 3,912 days (10.7 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 20.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (2 entries)
- Days to follow up: 105 days; Progression or recurrence anatomic site: Bone, NOS; Days to first event: 105 days; First event: Progression.
- Days to follow up: 3,912 days (10.7 years); Year of follow up: 2018.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARGHY-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARGHY-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 3912
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.1
- ICDO Description: Retroperitoneum Periadrenal tissue Perinephric tissue Peripancreatic tissue Perirenal tissue Retrocecal tissue Retroperitoneal tissue
- Percent Tumor v/s Stroma: 20/80
- Site of Relapse: Bone
